Somatic mutation profile of tumor specimen TCGA-OR-A5JS-01A (aliquot TCGA-OR-A5JS-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JS, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 65.8 years (24,017 days).
Specimen TCGA-OR-A5JS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cad29fef-b094-4c8c-84bd-a40735155371.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JS-10A (Blood Derived Normal), aliquot TCGA-OR-A5JS-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5aabfc2c-8e7f-4c01-a93f-add9d090a15b

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 19, Silent 9, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 56/244 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 313/529 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1395773373, COSV100567301; called by muse, mutect2, varscan2
- ADD2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.083); catalogued as rs200519011, COSV52457097; called by muse, mutect2, varscan2
- DICER1 | c.3257del p.P1086Lfs*9 | Frame Shift Del (DEL) | VAF 57/149 reads (38%) | catalogued as COSV58623104; called by mutect2, pindel, varscan2
- DUSP6 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1172171465; called by muse, mutect2
- LYG2 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs916224882, COSV60716445; called by muse, mutect2, varscan2
- OTX2 | c.349C>G p.P117A (on ENST00000408990 / NM_172337.3; = p.P125A on NM_021728.4) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV59766535; called by muse, mutect2, varscan2
- PTPRD | c.4392G>T p.K1464N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61932744; called by muse, mutect2, varscan2
- RB1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 24/32 reads (75%) | catalogued as CD143491, COSV57297033; called by muse, mutect2, varscan2
- ROCK1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67698410; called by muse, mutect2, varscan2
- SNX18 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752584405, COSV57987618; called by muse, varscan2
- TLR2 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52605719; called by muse, mutect2, varscan2
- UNC5C | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763344659, COSV101497886; called by muse, mutect2, varscan2
- CADPS2 | c.167del p.S56Lfs*2 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- GK2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- GLB1L2 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITLN2 | c.158G>T p.C53F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.2859A>C p.L953F | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- RBMS3 | c.1177G>A p.E393K (on ENST00000383767 / NM_001003793.3; = p.E377K on NM_014483.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SEC63 | c.2099C>A p.S700* | Nonsense Mutation (SNP) | VAF 72/141 reads (51%) | called by muse, mutect2, varscan2
- SLC1A3 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 125/321 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SLC35C2 | c.1000_1007del p.G334Pfs*16 | Frame Shift Del (DEL) | VAF 110/129 reads (85%) | called by mutect2, varscan2
- SLF2 | c.713del p.L238Cfs*3 | Frame Shift Del (DEL) | VAF 49/151 reads (32%) | called by mutect2, varscan2
- SPRING1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SV2C | c.1503-2A>G p.X501_splice | Splice Site (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- ZNF558 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C1QTNF1 | c.555C>T p.F185= | Silent (SNP) | VAF 87/108 reads (81%) | called by muse, mutect2, varscan2
- GCN1 | c.480C>T p.H160= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs757475557; called by muse, mutect2, varscan2
- GP2 | c.99T>C p.Y33= | Silent (SNP) | VAF 76/192 reads (40%) | called by muse, mutect2, varscan2
- MYO10 | c.3003C>T p.D1001= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as rs370829048; called by muse, mutect2, varscan2
- PEX7 | c.771G>A p.V257= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, varscan2
- RNF212 | c.30C>T p.C10= | Silent (SNP) | VAF 62/194 reads (32%) | catalogued as rs1209148827; called by muse, mutect2, varscan2
- TOP2A | c.2004C>T p.F668= | Silent (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- TRPA1 | c.354C>A p.L118= | Silent (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- ZNF391 | c.297C>T p.H99= | Silent (SNP) | VAF 39/71 reads (55%) | called by muse, mutect2, varscan2
